Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19S, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19S-06A (Metastatic).

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Melanoma.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Right axillary dissection, scar revision, excision right arm lesion.

100-0-3

Melanoma, NOS 8720/3 12/15/10 Jw

Site Code: Axilla, NOS C44.5 -

FINAL DIAGNOSIS:

1. SKIN, RIGHT AXILLARY, EXCISION:

FIBROSIS, ACUTE AND CHRONIC INFLAMMATION (see comment).

2. SKIN AND RIGHT AXILLARY CONTENTS, EXCISION:

METASTATIC MELANOMA (GREATEST DIMENTION 2.5 CMM) IN 1 OF 12 LYMPH NODES.

3. SKIN, RIGHT ARM, EXCISION:

MILD MELANOCYTIC HYPERPLASIA, PAPILLARY DERMAL FIBROSIS AND MELANOPHAGES (see comment).

COMMENT:

#1. There is no evidence of malignancy.

#2. This diagnosis is supported by interpretation of immunoperoxidase stains (S100 and Melan-A).

#3. These changes are not diagnostic but suggestive of regression. If this is a site of prior biopsy, then the changes could be explained as "peri-cicatrical melanocytic hyperplasia". This diagnosis is supported by interpretation of immunoperoxidase stains (S100, and Melan-A).

Source: NCI Genomic Data Commons file 7f802eae-d632-45d4-b7df-d7454fedb814 (TCGA-ER-A19S.7CEBB665-0B8E-42E8-A2CE-24E428991004.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).